Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A70Y, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A70Y-01A (Primary Tumor).

[page 1 of 4]
Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

--- Clinical History ---
Brain mass.

ADDENDA:
Addendum added: [REDACTED]
Addendum added: [REDACTED]

---Final Pathologic Diagnosis---

- A. Left temporal tumor, biopsy:
- Low grade glioma (WHO grade II) See comment.
- B. Left temporal tumor, excision:
- Low grade glioma (WHO grade II), see comment.

Comment: The histological and immunohistochemical profile is that of a low grade glial neoplasm. However, the specific lineage is difficult to determine at this point. Fluorescent in-situ hybridization (FISH) for deletions 1p and 19q loci is being performed and an addendum will be reported subsequently.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the [REDACTED] laboratories in the [REDACTED] and are not required to have nor do they have FDA approval.

---Electronically Signed By---

---Addendum Report---

Addendum

Status: Signed Out

Detection of 1p36 and 19q by 1p36/ 1q25 and 19q13/19p13

ICD-O-3
Oligodendroglioma, grade II
9450/3
CSCE
Site Brain, supratentorial NOS
C71.8
path
Brain, temporal lobe
C71.2
QW8/22/13

[page 2 of 4]
[REDACTED]

Dual-Color Probe Sets

[REDACTED]

Case No [REDACTED]
Pathologist [REDACTED] Patient Name: [REDACTED]
Source of case [REDACTED] Patient MRN: [REDACTED]
Block used A1
Tissue fixation formalin-fixed tissue
Tissue source Brain

RESULTS

Ratio of 1p/1q: 0.84 Cell count of 1p/1q: 104
Ratio of 19q/19p: 0.67 Cell count of 19q/19p: 116
Interpretation of Results: A) 1p no loss; B) 19q loss

Interpretation of findings:

A) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 1q25 signals and 2 to 3 chromosome 1p36 signals (locus of interest), and the ratio of 1p36/1q25 Ratio was >0.8 . The results are consistent with no loss of the 1p36 locus of interest. B) (positive) The majority of tumors cells displayed 2 control chromosome 19p13 signals and 1 chromosome 19q13 signals (locus of interest). The ratio of 19q13/19p13 is <0.8 . The results are consistent with the loss of 1p36 locus of interest.

Number of Observers: 2

Test Interpreted By: [REDACTED]

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning

imaging workstation and accompanying imaging analysis software

The resultant FISH section/slide is then presented to the interpreting

Pathologist, who will reviews the FISH results from [REDACTED] and compares them to the results manually observed under Fluorescence Microscope.

Therefore the ratio is enumerated by computer-aided counting as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of 1p36 signals by the total number of 1q25 signals in at least 20 interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by

dividing the total number of 19q13 signals by the total number of 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping nuclei in the

neoplastic glial cells at two different areas of the sample. Cells with no signals or with signals of only one color are disregarded.

References ranges for our

laboratory for allelic loss versus no allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both

probe set 1 and 2 a ratio of less than 0.80 taken from at least 2 sets of 20 interphase nuclei at 2 different areas with nonoverlapping nuclei is consistent with

allelic loss. FISH and H&E stained slides have been reviewed by the interpreting pathologist.

Limitations

[REDACTED]

[page 3 of 4]
[REDACTED]

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the [REDACTED]

They have not been

cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Addendum

Status: Signed Out

A and B: Left temporal lobe, excision.

- Oligodendroglioma (WHO grade II).

In-situ hybridization detects deletion of 19q but intact 1p locus. The case was reviewed subsequently with [REDACTED] neuropathologist, who concurs.

[REDACTED]

---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Left temporal tumor: (FROZEN SECTION PERFORMED)
- Infiltrating glial neoplasm, favor low-grade.

Examining pathologist [REDACTED]

---MICROSCOPIC:---

Sections show a mild to moderately cellular infiltrating neoplasm composed of glial elements having round as well as elongated nuclei. Mitotic figures are not identified. Immunostain for GFAP is positive in a small number of cells and a Ki-67 stain shows a proliferation index of about 2-3%, as determined by manual immunohistochemistry method.

---SPECIMEN(S) RECEIVED:---

A: Brain Reg
B: Brain Reg

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number, one of which was submitted for frozen section.

[REDACTED]

[page 4 of 4]
[REDACTED]

A. The specimen is designated "left temporal tumor" and consists of a 3.0 x 1.5 x 1.2 cm portion of pale tan-pink soft tissue. The specimen is partially frozen and resubmitted as received in AF1. [REDACTED]

Summary of Cassettes: AF1, frozen section; A1-2, remainder of specimen

B. The specimen is designated "left temporal tumor" and consists of a 4.9 x 3.9 x 2.0 cm portion of pink-tan soft tissue. The specimen is serially sectioned revealing pale tan to dusky pink homogeneous cut surfaces. [REDACTED]

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

[REDACTED]

W 7/24/13

Unilateral/Synchronous Primary		/
Noted		/

[REDACTED]

Source: NCI Genomic Data Commons file 196f1774-fe98-4eaa-8e6f-be6e852c555b (TCGA-FG-A70Y.C736A839-8853-478E-BB5E-2A1ADCB0A46C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).